Somatic mutation profile of tumor specimen MP2PRT-PARVZW-TBP1-A (aliquot MP2PRT-PARVZW-TBP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PARVZW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (977 days).
Specimen MP2PRT-PARVZW-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5781402c-8d01-4828-aee9-37e39530c84a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARVZW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARVZW-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3439b224-2d98-447d-b9a9-0a35d5e6b57b

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EXT1 | c.1813C>T p.R605W | Missense Mutation (SNP) | VAF 117/445 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs146967463; called by muse, mutect2, varscan2
- MRC2 | c.953A>T p.K318M | Missense Mutation (SNP) | VAF 71/240 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57637917; called by muse, mutect2, varscan2
- NRAP | c.2873A>G p.E958G (on ENST00000359988 / NM_001322945.2; = p.E923G on NM_006175.4) | Missense Mutation (SNP) | VAF 57/234 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1450957691; called by muse, mutect2, varscan2
- LAMA5 | c.6379C>T p.H2127Y | Missense Mutation (SNP) | VAF 115/277 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- RASA4 | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 130/564 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- MDFIC | c.627G>T p.G209= | Silent (SNP) | VAF 84/365 reads (23%) | called by muse, mutect2, varscan2
- TRDJ1 | chr14:22449112 ins GGTA | 5'Flank (INS) | VAF 26/126 reads (21%) | called by mutect2, pindel, varscan2
